Gene-level copy-number profile of tumor specimen TCGA-30-1887-01A from TCGA case TCGA-30-1887, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 67.1 years (24,495 days).
Specimen TCGA-30-1887-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c7553a24-4cdc-42d7-9af7-8c4e1dc88e3b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1887-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a8f6d485-f5cc-4f9a-a6ea-465f136dc86b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,440; copy number 2: 20,924; copy number 3: 27,909; copy number 4: 4,665; copy number 5: 1,065; copy number 6: 1,868; copy number 7: 1,693; copy number 8: 29; copy number 9: 160; copy number 10: 42; copy number 11: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-30-1887-01): tumor purity 0.5, ploidy 3.01, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,943 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:42,896,946–43,030,535, 1 gene, copy number 7 (within-gene range 2–7): HOOK3.
- chr8:43,018,424–145,066,685, 1,562 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr12:42,238,447–47,079,959, 74 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr19:27,638,483–30,038,181, 60 genes, copy number 7–11: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.
- chr19:35,608,285–38,587,564, 147 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr20:9,537,370–9,839,076, 1 gene, copy number 8 (within-gene range 6–8): PAK5.
- chr20:9,835,556–11,345,855, 28 genes, copy number 8: AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2, SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1.
- chr20:22,885,670–23,421,519, 19 genes, copy number 7: CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479.
- chr20:24,679,547–25,868,225, 38 genes, copy number 7: AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2.
- chr20:31,514,410–31,723,989, 13 genes, copy number 9: HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.

Autosomal genes at a single copy (total copy number 1): 1,440. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
